Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A89V, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A89V-01A (Primary Tumor).

ICD O-3
Astrocytoma, grade III 94013
Site ^{CNS} Brain, supratentorial NOS C71.0
~~path~~ Brain, NOS C71.9
9/21/24/13

Astrocytic tumor with increased proliferation and some thrombosed vessels.

No necrosis detected.

For differential diagnosis Glioblastoma we asked for a second opinion. They also favor anaplastic astrocytoma.

No IDH1/IDH2 mutation.

Diagnosis:

anaplastic astrocytoma WHO grade III

Primary Malignancy History		✓

Untranslated original report is housed at the BCR

Source: NCI Genomic Data Commons file 458fd5fb-8f5c-4cd0-a8a8-400cc78a453c (TCGA-S9-A89V.2D3BF6FF-3A5D-4012-A84C-9E51D31770F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).